FM case AD7762 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/8d957b1a-3e8c-40eb-a899-3a6e7195f7fb

Male, 70.3 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the lung. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
